Somatic mutation profile of tumor specimen TCGA-B8-5549-01A (aliquot TCGA-B8-5549-01A-01D-1534-10) from TCGA case TCGA-B8-5549, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 53.6 years (19,561 days).
Specimen TCGA-B8-5549-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 888f3ea0-8d25-4bd8-8c5b-1312aba35399.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5549-10A (Blood Derived Normal), aliquot TCGA-B8-5549-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1dc543d9-3d80-4bc9-8476-2da58305ae56

The open-access MAF lists 61 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 14, Frame Shift Del 6, Splice Site 2, Frame Shift Ins 2, Intron 1, Splice Region 1, RNA 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.484T>C p.C162R | Missense Mutation (SNP) | VAF 31/64 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1553620313, CM951294, COSV56542418; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMDHD1 | c.1160A>G p.K387R | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.831); catalogued as rs1312254977, COSV57139480; called by muse, mutect2, varscan2
- ARID1A | c.5882G>A p.S1961N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV61382486; called by muse, mutect2, varscan2
- CCDC30 | c.2127C>A p.S709R (on ENST00000340612; = p.S666R on NM_001080850.3) | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as COSV59607844; called by muse, mutect2, varscan2
- CLCA2 | c.1423A>G p.S475G | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV65287922; called by muse, mutect2
- DENND11 | c.923G>T p.S308I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.119); catalogued as COSV72097735; called by muse, mutect2, varscan2
- EML5 | c.4712G>A p.G1571D (on ENST00000380664; = p.G1579D on NM_183387.3) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61348347; called by muse, mutect2, varscan2
- ENTHD1 | c.638T>A p.V213D | Missense Mutation (SNP) | VAF 154/459 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV57322429; called by muse, mutect2, varscan2
- GALM | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV55372728; called by muse, mutect2, varscan2
- GOLGA1 | c.1844A>C p.D615A | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV63024199; called by muse, mutect2, varscan2
- HMGN5 | c.662A>T p.K221I | Missense Mutation (SNP) | VAF 556/820 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100814820; called by muse, varscan2
- KCNH6 | c.358G>T p.G120W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59005224; called by muse, mutect2, varscan2
- KIF20A | c.1821C>T p.C607= | Splice Region (SNP) | VAF 35/93 reads (38%) | catalogued as COSV67510188; called by muse, mutect2, varscan2
- L1TD1 | c.828T>G p.F276L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63133700; called by muse, mutect2, varscan2
- LCMT1 | c.460C>G p.Q154E | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV66726001; called by muse, mutect2, varscan2
- MACF1 | c.9065C>A p.P3022H | Missense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as COSV57131182; called by muse, mutect2, varscan2
- MAP3K13 | c.2501+1G>A p.X834_splice | Splice Site (SNP) | VAF 109/315 reads (35%) | catalogued as COSV53992160; called by muse, mutect2, varscan2
- MARK1 | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as COSV65068417, COSV65069127; called by muse, mutect2, varscan2
- NPPA | c.269C>A p.A90D | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.153); catalogued as COSV56740297; called by muse, mutect2, varscan2
- OR1L3 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV59170178; called by muse, mutect2, varscan2
- OR6K2 | c.15T>G p.N5K | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV62743811; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.407C>A p.P136H (on ENST00000421990 / NM_001136042.2; = p.P118H on NM_025267.3) | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV64183675; called by muse, mutect2, varscan2
- RRBP1 | c.3103G>C p.E1035Q (on ENST00000377813 / NM_001365613.2; = p.E602Q on NM_004587.3) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs200276432, COSV55703424; called by muse, mutect2, varscan2
- SCN1A | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100319056, COSV57677395; called by muse, mutect2, varscan2
- SEC16B | c.2849A>G p.H950R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100381463; called by muse, mutect2
- SLC15A2 | c.1916C>G p.S639C | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1559856721, COSV55199108; called by muse, mutect2, varscan2
- SLC35D2 | c.194T>C p.M65T | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs147633936; called by muse, mutect2
- TAAR9 | c.212T>A p.I71N | Missense Mutation (SNP) | VAF 81/277 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV71512265; called by muse, mutect2, varscan2
- TCEAL8 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 90/136 reads (66%) | SIFT tolerated (0.27); PolyPhen benign (0.439); catalogued as COSV63506398, COSV63506541; called by muse, mutect2, varscan2
- TMEM38B | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101016341, COSV65950588; called by muse, mutect2, varscan2
- TUT7 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.095); catalogued as COSV52897023; called by muse, mutect2, varscan2
- USP34 | c.4406C>T p.S1469L | Missense Mutation (SNP) | VAF 121/325 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV68403409; called by muse, mutect2, varscan2
- ZBED9 | c.797A>T p.E266V | Missense Mutation (SNP) | VAF 133/395 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.329); catalogued as COSV71729585; called by muse, mutect2, varscan2
- ZNF189 | c.139T>C p.Y47H | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV52276000; called by muse, mutect2, varscan2
- ANKLE2 | c.1216_1218del p.T406del | In Frame Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- ATF7IP | c.2662del p.S888Lfs*22 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- DPEP3 | c.506_513del p.A169Vfs*2 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- MIA2 | c.1392_1392+8del p.X464_splice | Splice Site (DEL) | VAF 58/422 reads (14%) | called by pindel, varscan2
- MPDZ | c.1377_1378dup p.M460Kfs*2 | Frame Shift Ins (INS) | VAF 47/235 reads (20%) | called by mutect2, pindel, varscan2
- NIPBL | c.2635del p.E879Kfs*50 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- PRKCE | c.832del p.M278* | Frame Shift Del (DEL) | VAF 42/137 reads (31%) | called by mutect2, pindel, varscan2
- SNX10 | c.403del p.S135Lfs*17 | Frame Shift Del (DEL) | VAF 88/312 reads (28%) | called by mutect2, pindel, varscan2
- TMEM87A | c.788del p.G263Vfs*32 | Frame Shift Del (DEL) | VAF 14/119 reads (12%) | called by mutect2, pindel, varscan2
- ZNF300 | c.622dup p.S208Ffs*6 | Frame Shift Ins (INS) | VAF 63/200 reads (32%) | called by mutect2, pindel, varscan2
- ANK3 | c.7218T>C p.Y2406= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV55067965; called by muse, mutect2, varscan2
- ANXA2 | c.910A>C p.R304= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV60317596; called by muse, mutect2, varscan2
- ASH1L | c.5991C>T p.D1997= | Silent (SNP) | VAF 107/259 reads (41%) | catalogued as rs1437509860, COSV64210399; called by muse, mutect2, varscan2
- CCDC30 | c.1362T>C p.Y454= (on ENST00000340612; = p.Y411= on NM_001080850.3) | Silent (SNP) | VAF 80/191 reads (42%) | catalogued as COSV59607838; called by muse, mutect2, varscan2
- CDH18 | c.213T>A p.P71= | Silent (SNP) | VAF 92/258 reads (36%) | catalogued as rs769392828, COSV56939093; called by muse, mutect2, varscan2
- EPHB4 | c.1662G>A p.V554= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV62269642; called by muse, mutect2, varscan2
- FMNL2 | c.60T>C p.P20= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99979378; called by mutect2, varscan2
- GP1BA | c.1767A>C p.T589= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV56700042, COSV99851119; called by muse, mutect2, varscan2
- GPR12 | c.723G>A p.S241= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs770835683, COSV67344258; called by muse, mutect2, varscan2
- IL18RAP | c.1233C>T p.F411= | Silent (SNP) | VAF 92/272 reads (34%) | catalogued as rs140183707; called by muse, mutect2, varscan2
- SACS | c.2532A>C p.V844= | Silent (SNP) | VAF 36/216 reads (17%) | catalogued as COSV66543454; called by muse, mutect2, varscan2
- SLC12A6 | c.882T>C p.Y294= (on ENST00000354181 / NM_001365088.1; = p.Y243= on NM_005135.2) | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV51628225; called by muse, mutect2, varscan2
- ZFHX4 | c.10752G>A p.K3584= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV50913950; called by muse, mutect2, varscan2
- ZNF761 | c.2010C>T p.T670= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV61888812; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24048794 A>G | 5'Flank (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- FRMPD2B | n.657C>T | RNA (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- PDE4B | c.281+74301A>G | Intron (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2
